Gene-level copy-number profile of tumor specimen TCGA-50-6590-01A from TCGA case TCGA-50-6590, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 72.4 years (26,444 days).
Specimen TCGA-50-6590-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.fed25ca7-be84-417b-a371-d73b5c882d38.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-50-6590-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 842 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7b96317e-7277-4b81-8c09-c10bc7c3c6e6

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 924; copy number 2: 21,699; copy number 3: 21,530; copy number 4: 11,298; copy number 5: 3,386; copy number 6: 754; copy number 7: 41; copy number 8: 45; copy number 11: 2; copy number 13: 86; copy number 16: 16.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-50-6590-01A-12D-1854-01): tumor purity 0.25, ploidy 2.93, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 190 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:54,603,211–62,078,335, 102 genes, copy number 13–16 (within-gene range 4–36) (broad region; genes not listed).
- chr14:32,934,396–35,363,628, 41 genes, copy number 7 (within-gene range 5–7): NPAS3, AL161851.1, AL161851.2, EGLN3, EGLN3-AS1, AL356806.1, SPTSSA, RPL23AP71, EAPP, AL445363.3, AL445363.1, RNU1-27P, RNU1-28P, AL445363.2, SNX6, RPS19P3, Metazoa_SRP, RNU6-1261P, RPL23AP8, CFL2, RPL12P6, BAZ1A, RNU7-41P, AL121603.2, SRP54-AS1, AL121603.1, IGBP1P1, SRP54, FAM177A1, PPP2R3C, AL049776.1, PRORP, AL121594.1, RPL23AP70, SEPTIN7P1, MRPL57P8, DPRXP3, RPL7AP3, RPL9P3, PSMA6, AL133163.2.
- chr14:42,362,983–46,651,781, 46 genes, copy number 8–11 (within-gene range 5–11): AL442163.1, AL450442.1, AL442163.2, AL442163.3, YWHAQP1, AL163153.1, TUBBP3, HNRNPUP1, AL583809.1, KRT8P2, AL358913.1, ARHGAP16P, LINC02307, EIF4BP1, AL109766.1, YWHAZP1, AL161752.1, LINC02277, FSCB, AL356022.1, LINC02302, DOCK11P1, AL049870.2, AL049870.1, RRAGAP1, C14orf28, AL049870.3, KLHL28, TOGARAM1, AL121809.2, AL121809.1, PRPF39, SNORD58, SNORD127, FKBP3, FANCM, MIS18BP1, RNU6-552P, DNAJC19P9, AL162632.3, AL162632.1, AL162632.2, AL139354.1, LINC02303, LINC00871, RPL10L.
- chr14:46,960,423–46,960,546, 1 gene, copy number 11: AL359951.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
